Somatic mutation profile of tumor specimen MP2PRT-PAUNFW-TMP1-A (aliquot MP2PRT-PAUNFW-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUNFW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,306 days).
Specimen MP2PRT-PAUNFW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2d93e5c-47cf-4049-bd14-c973c5488a3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNFW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNFW-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f00728ce-43f0-4740-b680-a682e3237e04

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 18, Silent 13, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC113554.1 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 130/449 reads (29%) | catalogued as rs991007617; called by muse, mutect2, varscan2
- ADAMTS15 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 292/904 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399593895; called by muse, mutect2, varscan2
- DNMT3B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.341); catalogued as COSV52420968; called by muse, mutect2, varscan2
- FLT3 | c.1730A>C p.Q577P | Missense Mutation (SNP) | VAF 104/221 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54056525; called by muse, mutect2, varscan2
- GLRB | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1560962621, COSV52412316; called by muse, mutect2, varscan2
- LRRC30 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 193/790 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV67301639; called by muse, mutect2, varscan2
- MTTP | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs756001078, COSV99644819; called by muse, mutect2, varscan2
- PECR | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 89/191 reads (47%) | catalogued as rs771102215; called by muse, mutect2, varscan2
- SPIRE1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs774265265; called by muse, mutect2, varscan2
- TP63 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 192/414 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53223605; called by muse, mutect2, varscan2
- XKR7 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as rs1273258595; called by muse, mutect2, varscan2
- ZFPM2 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 170/564 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.309); catalogued as COSV65873588; called by muse, mutect2, varscan2
- BMPR1B | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EFCAB8 | c.2349T>G p.D783E | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GRIK1 | c.1968G>T p.W656C | Missense Mutation (SNP) | VAF 112/500 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H1-3 | c.294A>C p.K98N | Missense Mutation (SNP) | VAF 185/569 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXRA5 | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 142/305 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRBP | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 113/216 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- VCAN | c.9316C>T p.P3106S | Missense Mutation (SNP) | VAF 145/468 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZBED5 | c.330T>G p.Y110* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- ADARB2 | c.1629C>T p.G543= | Silent (SNP) | VAF 209/729 reads (29%) | catalogued as rs371274182; called by muse, mutect2, varscan2
- ARMCX2 | c.1158C>T p.R386= | Silent (SNP) | VAF 234/506 reads (46%) | catalogued as rs1424931203, COSV100168161; called by muse, mutect2, varscan2
- DNAH5 | c.4083C>T p.P1361= | Silent (SNP) | VAF 101/302 reads (33%) | catalogued as rs149691390; ClinVar: likely benign; called by muse, mutect2, varscan2
- IQCB1 | c.228T>C p.G76= | Silent (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- MUC2 | c.2088C>T p.D696= | Silent (SNP) | VAF 454/704 reads (64%) | catalogued as rs746519255; called by muse, varscan2
- NCAM1 | c.882C>T p.G294= | Silent (SNP) | VAF 139/444 reads (31%) | catalogued as COSV100378343; called by muse, mutect2, varscan2
- NOVA2 | c.93C>T p.G31= | Silent (SNP) | VAF 143/290 reads (49%) | catalogued as rs376342520; called by muse, mutect2, varscan2
- POTEE | c.2268G>A p.K756= | Silent (SNP) | VAF 121/403 reads (30%) | catalogued as rs549522754; called by muse, mutect2, varscan2
- PRICKLE2 | c.2403C>T p.Y801= (on ENST00000295902; = p.Y745= on NM_198859.4) | Silent (SNP) | VAF 68/426 reads (16%) | catalogued as rs532567960; called by muse, mutect2, varscan2
- SALL3 | c.858C>T p.F286= | Silent (SNP) | VAF 68/197 reads (35%) | catalogued as rs1261868803; called by muse, mutect2, varscan2
- SIRT4 | c.876G>A p.S292= | Silent (SNP) | VAF 164/363 reads (45%) | catalogued as rs746858573, COSV99177441; called by muse, mutect2, varscan2
- SLIT1 | c.1377C>T p.I459= | Silent (SNP) | VAF 200/614 reads (33%) | catalogued as rs530893146, COSV56592261; called by muse, mutect2, varscan2
- TP63 | c.762C>T p.N254= | Silent (SNP) | VAF 100/239 reads (42%) | catalogued as rs752535926, COSV53206184; called by muse, mutect2, varscan2
